Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABS8, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABS8-TTP1-A (Primary Tumor).

[page 1 of 15]
**Molecular Oncology
KRAS Mutation Analysis**

Patient Name: [REDACTED]

DOB [REDACTED]

Age: 71 yrs

SSN #: [REDACTED]

Gender: Female

Specimen #: [REDACTED]

Case #: [REDACTED]

Patient ID #: [REDACTED]

Date Collected: [REDACTED]

+14

Date Received [REDACTED]

+252

Referring Physician: [REDACTED]

Treating Physician: [REDACTED]

Client Lab ID #: [REDACTED]

Hospital ID #: [REDACTED]

Specimen ID #: [REDACTED]

Specimen(s) Received: 5 - Slide(s)

Body Site: Colon

Specimen Type: Paraffin embedded tissue

Clinical Data: Adenocarcinoma

Ethnicity:

RESULTS: Wild-type gene.

INTERPRETATION:

No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with resistance to anti-EGFR monoclonal antibody therapies in patients with colorectal cancer.

KRAS mutations occur in 30-50% of colorectal adenocarcinomas.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected.

This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

NSCLC

Mascoux C, Iannino N, et al. British Journal of Cancer. 2005; 92:131-139.

Pao W, Wang TY, et al. PLoS Medicine. 2005; 2(1):57-61.

Eberhard DA, Johnson BE, et al. J Clin Oncol. 2005; 23:5900-5909.

Han SW, Kim TY, et al. Clin Cancer Res. 2006; 12(6): 2538-2544.

CRC

DiFiore C, Blanchard F et al. Br J Cancer. 2007; 95:1166-1169.

Lievre A, Bachet J-B, et al. Cancer Res. 2006; 66:3982-3995.

Electronically Signed by: [REDACTED]

Reported by: [REDACTED]

[page 2 of 15]
Molecular Oncology
KRAS Mutation Analysis

Patient Name: [REDACTED]

DOB: [REDACTED]

Age: 71 yrs

SSN #: [REDACTED]

Gender: Female

Specimen #: [REDACTED]

Case #: [REDACTED]

Patient ID #: [REDACTED]

Date Collected: [REDACTED]

+12

Date Received: [REDACTED]

+252

Referring Physician: [REDACTED]

Treating Physician: [REDACTED]

Client Lab ID #: [REDACTED]

Hospital ID #: [REDACTED]

Specimen ID #: [REDACTED]

Specimen(s) Received: 5 - Slide(s)

Body Site: Colon

Specimen Type: Paraffin embedded tissue

Clinical Data: Adenocarcinoma

Ethnicity: [REDACTED]

RESULTS: Wild-type gene.

INTERPRETATION:

No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with resistance to anti-EGFR monoclonal antibody therapies in patients with colorectal cancer.

KRAS mutations occur in 30-50% of colorectal adenocarcinomas.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected.

This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

NSCLC

Mascaux C, Iannino N, et al. British Journal of Cancer. 2005; 92:131-139.

Pao W, Wang TY, et al. PLoS Medicine. 2005; 2(1):57-61.

Eberhard DA, Johnson BE, et al. J Clin Oncol. 2005 23:5900-5909.

Han SW, Kim TY, et al. Clin Cancer Res. 2006; 12(8): 2538-2544.

CRC

DiFlore C, Blanchard F et al. Br J Cancer. 2007; 96:1166-1169.

Lievre A, Bachet J-B, et al. Cancer Res. 2006; 66:3992-3995.

Electronically Signed by: [REDACTED]

Reported by: [REDACTED]

[page 3 of 15]
Patient Name:
Ordering Physician:
Treating Physician:
Ordering Facility:
Medical Record #:
Date of Birth, Sex:

Collection Date: +14
Received Date: +234
Report Date: +241
Integrated Oncology Ref #:
Specimen ID #:

Detection of Microsatellite Instability by PCR

INTERPRETATION:

High Microsatellite instability was detected.

High frequency microsatellite instability in colorectal cancer is associated with:

- Deficient DNA mismatch repair function.
- HNPCC and a subset of sporadic cancers.
- Synchronous and metachronous cancers and extracolonic tumors (endometrium, ovary, stomach, small bowel, ureter, and renal pelvis).
- Favorable prognosis.

Indication for Study: Colon Cancer

Specimen Type: Tissue - Paraffin Embedded - Rt Colon

Comments:

Microsatellite instability analysis of this patient's specimen revealed instability in 4 of the 5 markers analyzed. These results indicate high frequency microsatellite instability.

Colorectal carcinomas with indication of high microsatellite instability (MSI-H) have been associated with poor stage-specific survival after surgical and adjuvant therapies than those with MSS. To date, no significant difference in treatment response has been ascertained between MSI-L and MSS.

See report [REDACTED] for further information.

Microsatellite Marker	Result
BAT25	Unstable
BAT26	Unstable
D17S250	Unstable
D2S123	Unstable
D5S348	Stable

Instability is reported as either high (MSI-H) or low (MSI-L) or stable (MSS) dependant upon the number of markers analyzed that show instability. The reference range for instability is interpreted as follows:

	MSI-H	MSI-L	MSS
Markers show instability	≥ 2	1 of 5	0 of 5

Electronically Signed by [REDACTED] at [REDACTED]
Inc.

[page 4 of 15]
Patient Name:
Ordering Physician:
Treating Physician:
Ordering Facility:
Medical Record #:
Date of Birth, Sex:

Collection Date: +14
Received Date: +234
Report Date: +241
Integrated Oncology Ref #:
Specimen ID #:

Methodology:

The microsatellite instability (MSI) polymerase chain reaction (PCR) assay is performed using extracted tumor and non-tumor patient DNA as starting material. To detect MSI, a multiplex PCR reaction is performed using primers specific to five loci with either mononucleotide or dinucleotide repeats. The products are analyzed by capillary electrophoresis. Instability is determined by a change in the size of the resulting products, due to either insertion or deletion of repeating units in the microsatellite region, within a tumor when compared to normal tissue for each of the five loci. Instability is reported as either high (MSI-H), low (MSI-L) or stable (MSS) dependent upon the number of markers analyzed that show instability based on the Bethesda guidelines. [1] The sensitivity of the assay is minimum 15% of the tumor tissue section in the background of non-neoplastic elements.

Intended Use:

The microsatellite instability (MSI) assay is able to detect genomic instability of colorectal neoplasias through the detection of replication errors in regions of repetitive DNA or microsatellites. MSI may indicate the response to surgical or adjuvant therapy of patients with inherited or sporadic colon neoplasias. The results of this study are to be interpreted in the context of all clinical and laboratory findings.

References:

- M.A. Rodriguez-Blas et al, National Cancer Institute Workshop on Hereditary Nonpolyposis Colorectal Cancer Syndrome: meeting highlights and Bethesda guidelines. J. Natl. Cancer Inst. (Bethesda) 89:1756-1762/1997.
- R.C. Boland et al, A National Cancer Institute Workshop on Microsatellite Instability for Cancer Detection and Familial Predisposition: Development of International Criteria for the Determination of Microsatellite Instability in Colorectal Cancer. Cancer Res. 58:5248-5257/1998.
- N. Umetani et al, Diagnostic Primer Sets for Microsatellite Instability Optimized for a Minimal Amount of Damaged DNA from Colorectal Tissue Samples. Annals of Surgical Oncology. 7(4):278-280/1999.

Disclaimer

[page 5 of 15]
Patient Name:
Ordering Physician:
Treating Physician:
Ordering Facility:
Medical Record #:
Date of Birth, Sex:

Collection Date:
Received Date:
Report Date:
Integrated Oncology Ref #:
Specimen ID #:

+14
+234
+235

DNA Mismatch Repair Protein Analysis by IHC

Body site: Right Colon

The specimen submitted consists of 1 paraffin embedded block and 1 H&E section labeled [REDACTED] and is stated to be tissue from Right hemicolectomy with bladder cuff.

Clinical History

Adenocarcinoma

Diagnosis

THESE RESULTS SHOW ABSENT EXPRESSION OF THE MISMATCH REPAIR PROTEINS MLH-1 AND PMS2 AND ARE SUGGESTIVE OF A DEFICIENT DNA MISMATCH REPAIR FUNCTION, WHICH IS ASSOCIATED WITH MICROSATELLITE INSTABILITY IN GREATER THAN 95% OF COLORECTAL CANCER CASES.

Microscopic Description

Ranges and References for Mismatch Repair Protein (MMR) Expression by IHC Screening for Microsatellite Instability.
hMLH-1, hMSH-2, hMSH-6 and PMS2 Expressed = Preserved DNA Mismatch Repair Function.
hMLH-1, hMSH-2, hMSH-6 and PMS2 Not Expressed = Likely Deficient DNA Mismatch Repair Function.

A monoclonal antibody (clone A16-4) that recognizes PMS2 is used to perform immunohistochemistry on formalin-fixed, paraffin-embedded tissue. The expression of PMS2 in tumor nuclei is determined manually.

Additional studies: Microsatellite instability analysis by PCR.

Specimen [REDACTED]

ANTIBODY	RESULTS
Misc Single IHC	PMS2 Not Expressed
MLH1	Not Expressed
MSH2	Expressed
MSH6	Expressed

Tests

Misc Single IHC, MLH1, MSH2, MSH6

Methodology:

A monoclonal antibody (clone G168-15) that recognizes MLH1 is used to perform immunohistochemistry on formalin-fixed, paraffin-embedded tissue. The expression of MLH1 in tumor nuclei is determined manually.

A monoclonal antibody (clone FE11) that recognizes MSH2 is used to perform immunohistochemistry on formalin-fixed, paraffin-embedded tissue. The expression of MSH2 in tumor nuclei is determined manually.

A monoclonal antibody (clone BC/44) that recognizes MSH6 is used to perform immunohistochemistry on formalin-fixed, paraffin-embedded tissue. The expression of MSH6 in tumor nuclei is determined manually.

[page 6 of 15]
Patient Name:
Ordering Physician:
Treating Physician:
Ordering Facility:
Medical Record #:
Date of Birth, Sex:

Collection Date:
Received Date:
Report Date:
Integrated Oncology Ref #:
Specimen ID #:

+14
+234
+235

Intended Use:

MLH1 is useful in the identification of the mismatch repair gene defect.

MSH2 is useful in the identification of the mismatch repair gene defect.

MSH6 is useful in the identification of the mismatch repair gene defect.

Disclaimer

Reference Range:

1% or more weak to intense staining (1-3+) = Positive

Any image(s) that accompany this report is/are a representative image(s) only and should not be used to render a diagnosis.

The immunohistochemistry tests performed at [REDACTED] were validated on tissue fixed in 10% neutral buffered formalin. The performance characteristics of the tests performed on tissue processed in other fixatives is not known.

[page 7 of 15]
Patient Name:
Ordering Physician:
Treating Physician:
Ordering Facility:
Medical Record #:
Date of Birth, Sex:

Collection Date: +14
Received Date: +234
Report Date: +235
Integrated Oncology Ref #:
Specimen ID #:

Images

MLH-1

PMS2

MSH-2

MSH-6

[page 8 of 15]
[REDACTED]

Name: [REDACTED]

MRN: [REDACTED]

Account #:

Patient Type:

Room #:

Bed #:

Order Date:

+224

DOB:

Age:

Sex:

Accession #:

Exam Description:

SURGICAL PATHOLOGY

Admitting Diagnosis(es):

HEMATURIA

Dictated By:

Ordering Physician:

Attending Physician:

Primary Care Physician:

PATHOLOGY NUMBER: [REDACTED]

DATE COLLECTED: [REDACTED] +14

DATE RECEIVED: [REDACTED] +14

PREOPERATIVE DIAGNOSIS: Right colon cancer

POSTOPERATIVE DIAGNOSIS: Right colon cancer

PERTINENT CLINICAL HISTORY: Not given

SPECIAL REQUESTS/COMMENTS: Not given

SPECIMEN(S): A. Colon right, terminal ileum, bladder cuff

B. Colon margin

ADDENDUM: [REDACTED] +264

[REDACTED]

KRAS Mutation analysis:

Results: Wild-type gene

Interpretation: No mutations were identified at codons 12 and 13 of the KRAS gene.

Please see their report

END OF ADDENDUM

ADDENDUM, [REDACTED] +252

[REDACTED]

Detection of Microsatellite Instability by PCR:

Interpretation: High Microsatellite instability was detected.

[page 9 of 15]
PATHOLOGY REPORT

Name: [REDACTED]

MRN: [REDACTED]

Account #:

DOB: [REDACTED]

Order Date:

+224

Accession #:

Exam Description:

SURGICAL PATHOLOGY

Admitting Diagnosis(es):

HEMATURIA

DNA Mismatch Repair Protein Analysis by IHC:

Results:

Miscellaneous single IHC = PMS2 not expressed

MLH1 = Not expressed

MSH2 = Expressed

MSH6 = Expressed

Their diagnosis: These results show absent expression of the mismatch repair protein MLH-1 and PMS2 and are suggestive of a deficient DNA mismatch repair function which is associated with microsatellite instability in greater than 95% of colorectal cancers.

Please see their report.

END OF ADDENDUM

ADDENDUM, [REDACTED] +76

Colon Cancer Recurrence Score = 38

Please see their report.

END OF ADDENDUM

FINAL MICROSCOPIC DIAGNOSES:

A. Colon, Right, Terminal Ileum, Bladder Cuff.

POORLY DIFFERENTIATED ADENOCARCINOMA, HIGH GRADE.

Tumor Characteristics:

Specimen: Terminal ileum, cecum, ascending colon, appendix, and bladder cuff.

Procedure: Right hemicolectomy.

p Tumor Size: 4 x 4 cm.

Macroscopic Tumor Perforation: Not identified.

Histologic Type: Adenocarcinoma.

Histologic Grade: High grade, poorly differentiated.

[page 10 of 15]
PATHOLOGY REPORT

Name:

MRN:

Account #:

DOB:

Order Date:

+224

Accession #:

Exam Description:

SURGICAL PATHOLOGY

Admitting Diagnosis(es):

HEMATURIA

Microscopic Tumor Extension: Tumor is adherent to other organ (to bladder cuff).

Margin:

Proximal margin: Not involved by tumor.

Distal margin: Not involved by tumor.

Mesenteric margin: Involved by tumor.

Lymphovascular Invasion: Identified.

Perineural Invasion: Not identified.

Tumor Deposits: Not identified.

Appendix with invasive carcinoma in the muscularis propria.

Portion of bladder cuff showing invasive carcinoma in the muscularis propria

Uninvolved small intestine without specific pathologic changes.

Two of eleven lymph nodes is involved by tumor (2/11).

Pathologic Staging: pT4b, pN1b, pMx.

B. Colon Margin:

Fragment of small bowel and colonic tissue without specific pathologic changes.

No tumor identified.

GROSS EXAMINATION:

A. Specimen is received in formalin in a container labeled with the patient's name [REDACTED] and "colon, right terminal ileum, and bladder cuff." Specimen consists of a segment of colon with attached segment of ileum and appendix. The total specimen measures 21 x 10 x 4 cm. Also present separately is a fragment omentum that measures 25 x 10 x 0.6 cm. The segment of colon has been stapled at the distal end. The staples are separated. The lumen is opened. The serosal surface of the colon shows abundant adhesions at the level of the cecum. The small bowel measures 9 cm in length and 3.6 cm in open-faced diameter. The mucosal surface is pink-tan and folded in most areas. In the distal portion of the small bowel just adjacent to the ileocecal valve, there is an area of flattening of the mucosa measuring 3 x 2 cm. No other lesions are noted in the mucosa of the small bowel. The lumen of the large bowel measures 14 cm in length and 7cm in open-faced diameter. Just distal to the ileocecal valve approximately 2 cm from the ileocecal valve, there is a polyp that measures 1 cm in maximum dimension. The cecum of the colon shows a constricting, napkin-ring mass that is necrotic and extends from just beneath the ileocecal valve up to the appendiceal orifice, which is at the tip of the cecum. The mass is approximately 4 x 4 x 4 cm and has a central, necrotic lumen. The serosal surface shows abundant adhesions, with a bladder cuff in an area measuring up to 3 x 3 x 1 cm. No other lesions are noted. The appendix is subcecal and measures 4 cm x 1 cm. The serosal surface of appendix is unremarkable. Sectioning reveals the lumen. Specimen is sectioned and submitted representatively. Probable lymph nodes are also submitted. The piece of

[page 11 of 15]
PATHOLOGY REPORT

Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Account #: [REDACTED]

Order Date: [REDACTED]

Accession #: [REDACTED]

Exam Description:
SURGICAL PATHOLOGY

Admitting Diagnosis(es):
HEMATURIA

mesentery present separately in the container is yellow-tan and fatty, and otherwise unremarkable. Sectioning reveals no masses. It is submitted also representatively.

Cassette 1: Proximal ileal margin.

Cassette 2: Distal colonic margin.

Cassette 3: Sections from the ileum in the flattened area with adjacent tumor.

Cassette 4: Ileocecal valve.

Cassette 5: Small polyp at 1 cm away from the ileocecal valve.

A6 to A9: Sections from the tumor with adjacent adherent tissue.

A10: Tumor in relation to the appendiceal orifice.

A11: Normal colon away from tumor.

A12: Sections from the appendix.

A13 and A14: Tumor in relation to the adherent probable bladder.

A15: One lymph node, bisected.

A16: Multiple lymph nodes.

A17: Multiple lymph nodes.

A18: Representative sections from the mesentery.

Totally, 18 cassettes submitted representatively.

B. Specimen is received in formalin in a container labeled with the patient's name [REDACTED] and "colon margin." Specimen consists of 2 fragments of bowel tissue that measures 3.5 cm in diameter and 1 cm in width. It is submitted entirely in 2 cassettes, B1 and B2.

DICTATED BY: [REDACTED]

CPT CODE: [REDACTED]

D Date / Time: [REDACTED] +18

T Date / Time: [REDACTED] +18

R Date / Time: [REDACTED]

S Job #: [REDACTED]

D Job #: [REDACTED]

MT: [REDACTED]

D Date / Time: [REDACTED] +74

T Date / Time: [REDACTED] +74

[page 12 of 15]
PATHOLOGY REPORT

Name: [REDACTED]
MRN: [REDACTED] DOB: [REDACTED]
Account #: [REDACTED] Order Date: [REDACTED] +224
Accession #: [REDACTED] Exam Description: SURGICAL PATHOLOGY Admitting Diagnosis(es): HEMATURIA

R Date / Time: [REDACTED]
S Job #: [REDACTED]
D Job #: [REDACTED]
MT: [REDACTED]

D Date / Time: [REDACTED] +252
T Date / Time: [REDACTED] +252
R Date / Time: [REDACTED]
S Job #: [REDACTED]
D Job #: [REDACTED]
MT: [REDACTED]

D Date / Time: [REDACTED] +263
T Date / Time: [REDACTED] +263
R Date / Time: [REDACTED]
S Job #: [REDACTED]
D Job #: [REDACTED]
MT: [REDACTED]

[page 13 of 15]
Report of Roentgen Findings

Department of Radiology

+236

Patient Name: [REDACTED] Age: [REDACTED] Sex: F MRN: [REDACTED] Exam Date: [REDACTED]

Patient Location: [REDACTED]

Exam: [REDACTED]

ACC: [REDACTED]

tumor metabolic imag/pet / radiology only

CSN #: [REDACTED]

Patient Status: O

Requesting Physician: [REDACTED]

Attending Physician: [REDACTED]

Report To Name(s): 1) MOBILE PET, INTEGRAL IMAGING 2) [REDACTED]

CPT4 Codes: [REDACTED]

History:

Signs & Symptoms: COLON CA - RESTAGING

FINAL

+224

+223

CLINICAL HISTORY: Female patient, 71 years old, with colon cancer. Patient presents for restaging. Patient also with bladder cancer. No prior PET/CT is available for comparison. Correlation is made with the chest CT report from [REDACTED] and CT urogram from [REDACTED].

TECHNIQUE: This PET/CT study was performed on [REDACTED]. The blood glucose prior to injection was 111 mg/dl. Images were acquired from the base of the skull to mid thighs 60 minutes post injection of 17 mCi F-18 FDG and administration of dilute oral contrast. Image acquisition was done in two separate sessions as the patient needed to void during the scan. Axial, coronal and sagittal PET reconstructions with and without attenuation correction were interpreted. Corresponding CT images were acquired and reviewed alongside the PET images. The low dose unenhanced CT images were used for attenuation correction and anatomic correlation only.

COMMENT:

There are no foci of abnormal uptake in the neck, chest or abdomen to suggest FDG avid malignancy.

Within the pelvis, on the initial images there is an intense focus of uptake in the anterior pelvis just right of midline that appears to localize to a small bowel loop with SUV Max 8.6. On the second image set acquired after the patient voided there is no focal abnormality in this area but there is a focus of increased uptake along the right pelvic sidewall where there is an apparent 1.4 x 1.1 cm nodule near the right adnexa with an SUV max 9.1. This likely represents a bowel or mesentery-based focus that has moved with voiding.

There appears to be asymmetric soft tissue within the bladder which is not well distended. Excreted activity within the bladder precludes accurate evaluation for intravesicular hypermetabolic disease. There does, however, appear to be focal abnormal uptake in the right superolateral bladder which is likely hypermetabolic disease.

There is no abnormal uptake associated with a lobulated opacity within the right middle lobe bronchus which is associated with decreased attenuation in the lung parenchyma. This could represent chronic mucous plugging/bronchiectasis or neoplastic etiology such as carcinoid is possible.

There are vascular calcifications. A right chest port has its tip at the cavoatrial junction. There is diverticulosis. There has been a right hemicolectomy with unremarkable appearance of the anastomosis.

Tracer distribution is otherwise physiologic.

IMPRESSION:

1. There is intense focal uptake which appears to be adjacent to a bowel loop and moves between the image sets. This likely represents a bowel or mesenteric implant as its location would not be typical for excreted urine on the early image. Evaluation of the bladder is limited as discussed above. Otherwise, no evidence of FDG avid malignancy.
2. Decreased attenuation of the right middle lobe along with an opacity in right middle lobe bronchus. This is reportedly stable and most likely represents mucus plugging/bronchiectasis but an indolent neoplasm such as carcinoid would be in the differential. Correlation is suggested. A cluster of nodules in the right middle lobe appears inflammatory.

Responsible Providers:

Electronically signed by: +237

Transcribed By: [REDACTED]

+237

Authenticated By: [REDACTED]

+237

[page 14 of 15]
Department of Radiology

+346

Date of Birth: Age: Sex: MRN: Exam Date:

71 Y

Patient Location:

Exam:

tumor metabolic imag/pet / radiology only

ACC

Requesting Physician:

CSN #:

Patient Status: O

PET

CPT4 Codes:

History:

Signs & Symptoms: COLN CA, BLADDER CA - RESTAGING

FINAL

CLINICAL HISTORY: Female patient, 71 years old, with colon and bladder cancer, on chemotherapy. Patient presents for restaging. Comparison PET/CT +236

TECHNIQUE: The blood glucose prior to injection was 112 mg/dl. Images were acquired from the base of the skull to mid thighs 60 minutes post injection of 16.4 mCi F-18 FDG and administration of dilute oral contrast. Axial, coronal and sagittal PET reconstructions with and without attenuation correction were interpreted. Corresponding CT images were acquired and reviewed alongside the PET images. The low dose unenhanced CT images were used for attenuation correction and anatomic correlation only.

COMMENT:

There is no abnormal FDG uptake. The previously seen focus of moderate FDG uptake in the right anterior hemipelvis is no longer present; this may represent interval treatment effect or the initial finding may have been artifactual.

Status post right hemicolectomy. There is mild segmental uptake in the rectosigmoid colon, likely physiologic.

There is stable appearance of a 1.5 cm lobulated mass in the central right upper lobe with stable air trapping throughout much of the right upper lobe. The mass is without increased FDG uptake. This may represent chronic mucus plugging or indolent neoplasm such as carcinoid. There is mass effect on the right middle lobe which is displaced posteriorly. Mild scarring in the anterior right lung has improved, likely reflecting decreased associated atelectasis.

Urinary bladder is not well evaluated. It is poorly distended on CT and normal excreted tracer in the urine obscures evaluation of the bladder wall on PET. Tracer distribution is otherwise physiologic.

Colonic diverticula. Atherosclerosis. Degenerative changes of the spine. The cardiac left atrium is enlarged. Surgical clips left breast.

IMPRESSION:

No evidence of FDG avid malignancy. Interval resolution of right pelvic hypermetabolic focus which may reflect interval treatment response or the finding may have been artifactual on the prior study. Right hemicolectomy.

Stable 1.5 cm lobulated nodule in the right upper lobe with distal air trapping may represent indolent neoplasm or chronic mucus plug. Comparison with oldest available chest CT is recommended, along with continued follow up with chest CT.

Responsible Provider:

+345

Electronically signed by:

Contributing Providers:

Transcribed By:

Authenticated By:

+345
+345

[page 15 of 15]
Department of Radiology

+874

Patient Name

Date of Birth

Age

Sex

MRN

Exam Date

Patient Location

Exam

tumor metabolic imag/pet / radiology only

ACC

CSN #:

Patient Status: 0

Requesting Physician

Attending Physician

Report To Name(s): 1) MOBILE PET, INTEGRAL IMAGING 2)

CPT4 Codes:

History:

Signs & Symptoms:

colon and bladder ca - restaging

+680

FINAL

+560

CLINICAL HISTORY: Female patient, 72 years old, with history of colon cancer and bladder cancer status post radiation therapy (completed) and chemotherapy (completed). Patient presents for restaging. Comparison: +509

TECHNIQUE: The blood glucose prior to injection was 101 mg/dl. Images were acquired from the base of the skull to mid thighs 62 minutes post injection of 16.5 mCi F-18 FDG and administration of dilute oral contrast. Axial, coronal and sagittal PET reconstructions with and without attenuation correction were interpreted. Corresponding CT images were acquired and reviewed alongside the PET images. The low dose unenhanced CT images were used for attenuation correction and anatomic correlation only.

COMMENT:

There is a new right-sided level 2 cervical lymph node which measures 1.0 x 0.7 cm with maximum SUV of 3.0. A right-sided level 1B lymph node measures 1.0 x 0.6 cm with maximum SUV of 1.9 (previously not FDG avid, measuring 0.8 x 0.4 cm).

The patient is status post right hemicolectomy. Physiologic FDG activity is again seen within the remaining colon. Excreted radiotracer activity within the bladder precludes evaluation of the bladder wall. Two newly FDG avid lymph nodes are seen in the left inguinal region with the largest node measuring 1.2 x 0.9 cm with maximum SUV of 2.1 (previously not FDG avid, measuring 0.8 x 0.7 cm).

A focus of increased FDG activity is seen within the T7 vertebral body which measures 3.1 Max SUV (previously 3.3 Max SUV), with mild associated sclerosis which extends to the endplate and is unchanged compared to prior study dated. This likely represents a Schmorl's node.

Tracer distribution is otherwise physiologic.

+387

Additional CT findings:

Right-sided port with its tip at the cavoatrial junction. Scarring at the right lung apex. Bronchial atresia is again noted within the right upper lobe with surrounding air trapping and hyperexpansion; associated mucous plugging has improved compared to the prior study. Postsurgical changes of the left breast. Atherosclerotic calcification of the aorta and its branches.

IMPRESSION:

1. No evidence of FDG avid malignancy. New mildly FDG avid right cervical and left inguinal lymphadenopathy is nonspecific; a reactive etiology is favored but follow-up is recommended.
2. Bronchial atresia of the right upper lobe with interval improvement in mucous plugging.

Responsible Providers:

Electronically signed by:

Contributing Providers:

Transcribed By:

+875

+875

+875

Page 1 of 1

Source: NCI Genomic Data Commons file d9df83e1-b1f7-48d2-adcb-569b98c8556c (ER0010 ER-ABS8 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).